Somatic mutation profile of tumor specimen af95e2c6-25c4-4ab8-bf06-3e15ff (aliquot af95e2c6-25c4-4ab8-bf06-3e15ff_D6_1) from CPTAC case 04OV024, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen af95e2c6-25c4-4ab8-bf06-3e15ff: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66dff8f2-b8af-4c4d-b63c-bfe5af2c87c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen beb66f4d-8bfc-4d56-abaf-4bdba1 (Blood Derived Normal), aliquot beb66f4d-8bfc-4d56-abaf-4bdba1_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f5194c5-3f9b-4aa2-a75d-a195f8c751e3

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, Intron 4, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 1, In Frame Del 1, 3'UTR 1, 5'Flank 1, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 316/419 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.4059G>C p.K1353N (on ENST00000272895 / NM_173076.3; = p.K1035N on NM_015657.3) | Missense Mutation (SNP) | VAF 144/670 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55954536; called by muse, mutect2
- ADCY6 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 149/358 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs148986045; called by muse, mutect2, varscan2
- AKT2 | c.153dup p.N53Kfs*77 | Frame Shift Ins (INS) | VAF 273/772 reads (35%) | catalogued as rs1444704050; called by mutect2, pindel, varscan2
- CNTNAP5 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs756574947; called by muse, mutect2, varscan2
- JAK2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765494796; called by muse, mutect2, varscan2
- KLHL4 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1246515303, COSV64147140; called by muse, mutect2, varscan2
- MUC5AC | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 185/269 reads (69%) | SIFT deleterious (0); catalogued as rs1348118010; called by muse, mutect2, varscan2
- PLIN3 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.147); catalogued as rs763568905; called by muse, mutect2, varscan2
- POLG | c.3323A>G p.Y1108C | Missense Mutation (SNP) | VAF 293/719 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765949668, COSV51521349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSMB8 | c.173G>T p.G58V (on ENST00000374882 / NM_148919.4; = p.G54V on NM_004159.5) | Missense Mutation (SNP) | VAF 251/868 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs570855945; called by muse, mutect2, varscan2
- RIPOR3 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192351933; called by muse, mutect2, varscan2
- RUNX1T1 | c.1372C>T p.R458C (on ENST00000265814 / NM_001198628.1; = p.R431C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1381105316, COSV56138759; called by muse, mutect2, varscan2
- SEC14L5 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 105/130 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1485089286; called by muse, mutect2, varscan2
- SLC25A2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 241/313 reads (77%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs781798125, COSV53404985, COSV53405078; called by muse, mutect2, varscan2
- SLC38A6 | c.162G>T p.L54F | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50785031; called by muse, mutect2, varscan2
- SYNE2 | c.18723+1G>T p.X6241_splice | Splice Site (SNP) | VAF 144/371 reads (39%) | catalogued as COSV59938878; called by muse, mutect2, varscan2
- SYT14 | c.1262T>C p.I421T | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1441049237; called by muse, mutect2, varscan2
- TMEM229A | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs1221356336; called by muse, mutect2, varscan2
- TRIM71 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 173/383 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67470116; called by muse, mutect2, varscan2
- TRPV2 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 183/258 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV100641425; called by muse, mutect2, varscan2
- ADGRL2 | c.1924G>A p.D642N (on ENST00000370717 / NM_001366005.1; = p.D629N on NM_012302.4) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC3 | c.1406A>T p.D469V | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C11orf95 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- C2orf42 | c.1303T>G p.W435G | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C8orf48 | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- C8orf58 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 126/238 reads (53%) | called by muse, mutect2, varscan2
- CD1C | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 368/704 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CENPI | c.1610T>A p.I537N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- COL4A5 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FEM1B | c.1472C>G p.A491G | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- GLRA3 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2
- GRIA2 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 157/213 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPDL | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2
- KDM2A | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- LPAR4 | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 166/549 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MED13L | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 171/450 reads (38%) | called by muse, mutect2, varscan2
- METTL8 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- MOGAT1 | c.453_467del p.F152_V156del | In Frame Del (DEL) | VAF 72/450 reads (16%) | called by mutect2, pindel, varscan2
- PARD3B | c.3358C>T p.H1120Y (on ENST00000406610 / NM_001302769.2; = p.H1051Y on NM_057177.7) | Missense Mutation (SNP) | VAF 110/501 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PPARG | c.728C>G p.A243G (on ENST00000287820 / NM_015869.5; = p.A213G on NM_005037.7) | Missense Mutation (SNP) | VAF 188/412 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by mutect2, varscan2
- SIPA1L3 | c.845del p.K282Rfs*24 | Frame Shift Del (DEL) | VAF 110/306 reads (36%) | called by mutect2, pindel, varscan2
- SLC44A3 | c.770G>A p.G257D (on ENST00000271227 / NM_001114106.3; = p.G209D on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- SOCS4 | c.1144A>T p.I382F | Missense Mutation (SNP) | VAF 171/390 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TMEM8B | c.1085C>G p.T362R | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VCAN | c.6927_6963del p.E2310Kfs*6 | Frame Shift Del (DEL) | VAF 90/409 reads (22%) | called by mutect2, pindel, varscan2
- VPS51 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASQ1 | c.570C>T p.D190= | Silent (SNP) | VAF 74/258 reads (29%) | catalogued as rs377154249; called by muse, mutect2, varscan2
- COL11A1 | c.3174A>T p.S1058= | Silent (SNP) | VAF 133/349 reads (38%) | called by muse, mutect2, varscan2
- CYP7A1 | c.124C>T p.L42= | Silent (SNP) | VAF 158/393 reads (40%) | catalogued as rs1429939198, COSV56966263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCM | c.2137T>C p.L713= | Silent (SNP) | VAF 78/196 reads (40%) | called by muse, mutect2, varscan2
- GRIA1 | c.2589C>T p.S863= | Silent (SNP) | VAF 268/521 reads (51%) | catalogued as rs369539202; called by muse, mutect2, varscan2
- KCNC2 | c.45G>T p.G15= | Silent (SNP) | VAF 96/242 reads (40%) | catalogued as COSV100128120; called by muse, mutect2, varscan2
- KRT73 | c.51C>T p.F17= | Silent (SNP) | VAF 97/207 reads (47%) | called by muse, mutect2, varscan2
- PSG3 | c.246C>T p.Y82= | Silent (SNP) | VAF 135/323 reads (42%) | catalogued as rs375731618; called by muse, mutect2, varscan2
- SYNE1 | c.14160G>T p.L4720= (on ENST00000367255 / NM_182961.4; = p.L4649= on NM_033071.3) | Silent (SNP) | VAF 276/391 reads (71%) | called by muse, mutect2, varscan2
- TMEM179B | c.16C>T p.L6= | Silent (SNP) | VAF 90/189 reads (48%) | catalogued as rs1281154981; called by muse, mutect2, varscan2
- TNXB | c.2913G>A p.E971= | Silent (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- WDR90 | c.1011C>T p.H337= | Silent (SNP) | VAF 64/632 reads (10%) | catalogued as rs764589889; called by muse, mutect2
- EPB41L5 | c.1337+3329G>T | Intron (SNP) | VAF 69/314 reads (22%) | called by muse, mutect2, varscan2
- FKBP1B | c.-24A>G | 5'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- FLI1 | c.231-3321delinsCCTC | Intron (INS) | VAF 68/133 reads (51%) | called by pindel, varscan2*
- GATA3 | chr10:8050876 C>A | 5'Flank (SNP) | VAF 51/201 reads (25%) | called by muse, mutect2, varscan2
- OR4F13P | n.1212_1220del | RNA (DEL) | VAF 48/200 reads (24%) | called by mutect2, pindel, varscan2
- RAB3GAP1 | c.2710-852C>T | Intron (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- RABL6 | c.*177C>G | 3'UTR (SNP) | VAF 113/143 reads (79%) | called by muse, mutect2, varscan2
- TPM1 | c.240+4379G>C | Intron (SNP) | VAF 107/244 reads (44%) | called by muse, mutect2, varscan2
